TCGA case TCGA-CR-7385 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Tonsil; Tissue source site: Vanderbilt University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9f89510c-ed07-471f-b35e-7c87c237b9fe

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C09.9; Tissue or organ of origin: Tonsil, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 42.4 years (15,477 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC clinical T: T2; AJCC clinical N: N2b; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: M0; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 997 days (2.7 years).
   Pathology details: Consistent pathology review: Yes; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 87 days; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 87 days; Course number: 1; Treatment anatomic sites: Primary Tumor Field.

Follow-up (1 entry)
- Days to follow up: 997 days (2.7 years); Disease response: Tumor Free.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 2.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 0.01685; Tobacco smoking onset year: 1987; Tobacco smoking quit year: 1989.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CR-7385-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.1; Intermediate dimension: 0; Shortest dimension: 0.
  Slide TCGA-CR-7385-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-CR-7385-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: No; Lymph node neck dissection indicator: No; Margin status: Negative; Lymphovascular invasion: Yes; Tobacco smoking history indicator: 3.
- Drug treatment: Regimen number: 1.
- Drug treatment, Route of administrations: Route of administration: IV.
- Follow-up form: New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 997 days; disease-specific survival: no event (censored), 997 days; progression-free interval: no event (censored), 997 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CR-7385-01A-11D-2010-01): tumor purity 0.51, ploidy 1.94, whole-genome doublings 0.
